TARGET case TARGET-30-PASXNN — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Heart, mediastinum, and pleura. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2abcefac-8e1e-5c28-89cd-3c3a1d8489f3

Demographics
Sex at birth: male; Age at index: 9 years; Vital status: Alive.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; ICD-10 code: C38.3; Tissue or organ of origin: Mediastinum, NOS; Classification of tumor: primary; Age at diagnosis: 9.9 years (3,598 days); Year of diagnosis: 2009; Days to last follow up: 3,131 days (8.6 years); Cog neuroblastoma risk group: High Risk; Inpc grade: Undifferentiated or Poorly Differentiated; INSS stage: Stage 4; Mitosis karyorrhexis index: Intermediate.
   Pathology details: Necrosis percent: 10; Percent tumor nuclei: 80.
   Treatment given: Protocol identifier: ANBL00B1.
   Treatment given: Protocol identifier: ANBL0532.

Follow-up (2 entries)
- Days to follow up: 2,597 days (7.1 years); Days to first event: 2,597 days (7.1 years); First event: Event.
- Days to follow up: 3,131 days (8.6 years); Year of follow up: 2018.

Molecular and laboratory tests
- MYCN amplification: Not Amplified.
- Test: Abnormal, NOS; Ploidy: Hyperdiploid.

Biospecimens (2 samples)
- Sample TARGET-30-PASXNN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PASXNN-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Discovery_20230523.xlsx (sheet Clinical Data):
- First Event: Event
- Overall Survival Time in Days: 3131
- Protocol: ANBL00B1, ANBL0532
- Ploidy: Hyperdiploid (DI>1)
- Ploidy Value: 1.15
- Histology: Unfavorable
- Percent Tumor v/s Stroma: 80/20
